Gene-level copy-number profile of tumor specimen TARGET-10-PASKAD-09A from TARGET case TARGET-10-PASKAD, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.4 years (3,809 days).
Specimen TARGET-10-PASKAD-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.daef9953-a307-51e5-8c3a-d67438207e83.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PASKAD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 357 have no estimate.
https://portal.gdc.cancer.gov/files/5097c3a7-e026-4224-86e4-2a5131526f21

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 566; copy number 1: 549; copy number 2: 58,842; copy number 3: 192; copy number 4: 1; copy number 5: 116.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:108,047,545–108,168,956, 1 gene (within-gene range 0–1): LEF1.
- chr7:38,256,337–38,340,998, 15 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,345,499, 1 gene: TRGV5P.
- chr7:142,636,924–142,786,224, 19 genes: TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–1): AL359922.1.
- chr9:21,892,188–21,995,301, 4 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr14:106,440,950–106,443,583, 2 genes: IGHVII-40-1, IGHV3-41.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 116 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:19,026,001–19,032,626, 2 genes, copy number 5 (within-gene range 2–5): GTF2IP3, AL137001.1.
- chr14:105,785,505–106,436,555, 113 genes, copy number 5 (broad region; genes not listed).
- chr16:78,890,231–78,892,302, 1 gene, copy number 5: AC027279.4.

Autosomal genes at a single copy (total copy number 1): 549. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
